Somatic mutation profile of tumor specimen TARGET-20-PARFMY-09A (aliquot TARGET-20-PARFMY-09A-01D) from TARGET case TARGET-20-PARFMY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.6 years (6,440 days).
Specimen TARGET-20-PARFMY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f8f3e2e-5eff-4318-8dc0-e1e3807a4de9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARFMY-14A (Bone Marrow Normal), aliquot TARGET-20-PARFMY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0824960c-094c-44a4-b745-fea2eb58f0e6

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs397507540, CM053389, CM067454, COSV61004831; ClinVar: pathogenic; called by muse, varscan2
- CHD4 | c.3446G>A p.R1149Q (on ENST00000357008 / NM_001363606.2; = p.R1162Q on NM_001273.5) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58903721; called by muse, mutect2, varscan2
- CREBBP | c.3710G>A p.C1237Y | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52115539, COSV99270266; called by muse, mutect2, varscan2
- PTPN11 | c.1508delinsAGGC p.G503delinsEA | In Frame Ins (INS) | VAF 42/121 reads (35%) | catalogued as CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; called by pindel, varscan2*
- GAREM1 | c.2574C>A p.S858R (on ENST00000269209 / NM_001242409.2; = p.S857R on NM_022751.3) | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PPP2R2B | c.-180G>A | 5'UTR (SNP) | VAF 66/181 reads (36%) | catalogued as rs574499489; called by muse, mutect2, varscan2
